Gene-level copy-number profile of tumor specimen ALCH-B1V9-TTP1-A from ALCHEMIST case ALCH-B1V9, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 63.7 years (23,267 days).
Specimen ALCH-B1V9-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 12fd427c-cc70-4a9c-bc71-f41c62b51947.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1V9-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,233 have no estimate.
https://portal.gdc.cancer.gov/files/ad02c714-9ffc-4b75-bef6-d0ac5a63f0c5

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 74; copy number 1: 6,365; copy number 2: 50,960; copy number 3: 862; copy number 4: 117; copy number 5: 4; copy number 6: 4; copy number 7: 3; copy number 8: 1.

Homozygous deletions (total copy number 0; autosomes only): 74 genes in 25 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:96,938,923–96,939,203, 1 gene (within-gene range 0–2): Metazoa_SRP.
- chr3:46,835,111–46,882,172, 1 gene (within-gene range 0–1): MYL3.
- chr3:129,632,019–129,632,492, 1 gene: AC023162.1.
- chr4:573,880–576,295, 1 gene: TMEM271.
- chr6:35,468,401–35,512,896, 4 genes: RPL10A, MIR7111, TEAD3, TULP1.
- chr6:39,299,001–39,322,968, 2 genes: KCNK17, KCNK16.
- chr7:129,502,531–129,512,918, 1 gene: SMKR1.
- chr8:27,633,868–27,676,776, 1 gene: SCARA3.
- chr11:47,407,132–47,449,143, 3 genes (within-gene range 0–2): SLC39A13, PSMC3, RAPSN.
- chr11:67,056,847–67,072,017, 1 gene: RHOD.
- chr12:30,978,308–31,006,010, 1 gene (within-gene range 0–1): AC008013.1.
- chr12:123,081,384–123,092,821, 2 genes (within-gene range 0–2): PITPNM2-AS1, AC026362.2.
- chr14:18,333,726–18,412,264, 3 genes: CR383658.1, RNU6-458P, CR383658.2.
- chr14:18,560,047–18,568,790, 2 genes: CR383656.7, CR383656.13.
- chr14:67,386,984–67,412,167, 1 gene: PLEK2.
- chr14:91,232,532–91,259,003, 3 genes: GPR68, AL135818.1, AL135818.2.
- chr14:94,026,340–94,048,930, 1 gene (within-gene range 0–1): OTUB2.
- chr15:25,170,723–25,232,468, 34 genes (within-gene range 0–2): SNORD115-1, SNORD115-2, SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34.
- chr15:63,890,030–63,890,317, 1 gene: AC015914.2.
- chr15:85,770,496–85,771,163, 2 genes (within-gene range 0–1): MIR1276, AC021739.1.
- chr15:99,416,584–99,435,160, 2 genes: AC015660.3, AC015660.1.
- chr16:84,009,667–84,045,333, 3 genes: SLC38A8, RNA5SP432, AC040169.4.
- chr17:67,044,554–67,056,797, 1 gene: CACNG1.
- chr18:46,756,487–46,802,449, 1 gene (within-gene range 0–2): AC090241.2.
- chr20:3,846,799–3,876,123, 1 gene: MAVS.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 12 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:137,191,617–137,229,640, 6 genes, copy number 6–7: TPRN, TMEM203, NDOR1, RNF208, CYSRT1, RNF224.
- chr9:137,241,287–137,253,497, 4 genes, copy number 5: TUBB4B, FAM166A, STPG3-AS1, STPG3.
- chr9:137,299,631–137,302,271, 1 gene, copy number 6: NRARP.
- chr17:1,270,444–1,271,815, 1 gene, copy number 8: BHLHA9.

Autosomal genes at a single copy (total copy number 1): 4,021. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
